Surgical pathology report (de-identified scan), TCGA case TCGA-06-2563, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-2563-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

TCGA-06-2563

Patient Name:

Accession #:

Med: Rec.:

Phone Number:

DOB:

Gender: F

Client:

Physician(s):

Phy Location:

CLINICAL HISTORY

Left frontal brain tumor

OPERATIVE DIAGNOSES

Operation/Specimen: A: Left frontal brain tumor, biopsy

PATHOLOGICAL DIAGNOSIS:

Brain, left frontal tumor, biopsy: Glioblastoma (WHO Grade IV) (see comment).

COMMENT

Sections show a highly cellular, moderately pleomorphic and moderately vascularized glial tumor. Frequent mitotic figures are noted. Vascular proliferation and pseudopalisading necrosis are present in sections from blocks A2 and A4. Results of immunohistochemical and molecular studies will be reported in procedure addenda.

Electronically Signed Out

Senior Staff Pathologist

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered:

Date Reported:

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on paraffin tissue block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a

[page 2 of 3]
[REDACTED]

stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

[REDACTED] Senior Staff Pathologist

Consultant: [REDACTED]

Immunohistology

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

Immunostains are consistent with glioblastoma (see results below).

Results-Comments

The tumor background is diffusely GFAP positive and occasional tumor cells are GFAP positive.

The tumor is diffusely strongly p53 positive.

The Ki-67 labeling index is approximately 35%.

Electronically Signed Out

[REDACTED] Senior Staff Pathologist

PCR for EGFR variant III mutation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from tumor tissue paraffin block

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III (EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact. RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is then amplified using standard PCR technique for DNA templates. PCR products are detected by gel electrophoresis. The limit of detection of this assay has been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

[page 3 of 3]
provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

Senior Staff Pathologist

INTRA-OPERATIVE CONSULTATION

A. Brain, left frontal tumor, biopsy: High-grade glioma. Frozen section and smears performed at [redacted] and results reported to the Physician of Record. [redacted]

Senior Staff Pathologist

GROSS DESCRIPTION

A. Left frontal brain tumor - FS:

FIXATIVE: None

GENERAL: Received fresh from the operating room and labelled with the patient's name and medical record number is a single 1.5 x 1.1 x 0.7 cm tissue fragment with a heterogenous dark red to tan-pink, glistening and slightly convoluted external surface. Cut surfaces are variegated tan-pink to red-purple.

SECTIONS: A1 - Frozen section remnant; A2 - A4 - remainder of the tissue, entirely submitted

Resident Pathologist

ICD-9(s):

191.1 191.1

Histo Data

Part A: Left frontal brain tumor, biopsy

Taken:	Received:	
Stain/cnt	Block	Ordered
FS H/E x 1	1	
H/E x 1	1	
TPS H/E x 1	1	
H/E x 1	2	
EGFR vIII-curles x 1	3	
mGFAP-DA x 1	3	
H/E x 1	3	
MGMT-curles x 1	3	
MIB1-DA x 1	3	
P53DO7 x 1	3	
H/E x 1	4	

*** End of Report ***

Source: NCI Genomic Data Commons file f7fb0c5a-1efd-4317-8100-8dfec96a881d (TCGA-06-2563.4F0A8ABA-907A-4616-9704-DB9889C626D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).